Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0BP, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0BP-TTM1-A (Metastatic).

[page 1 of 19]
PATHOLOGY REPORT

Patient Name:
DOB/SEX:
Location:
Physician:

Collected: +4185
Received: +4185
Signed:
Submitting Physician:

Accession #:

ADDENDUM DIAGNOSIS #2

Additional immunohistochemical stains have been completed. The tumor cells show strong, diffuse immunoreactivity for P63 and CK34BE12. They are also immunoreactive for BerEP4. Tumor cells are negatively reactive for GATA-3, uroplakin III and S100p.

The staining pattern shows a mixture of squamous and glandular markers. However, in a large study of metastatic, poorly differentiated carcinomas, the finding of coexpression of CK5/6 and P63 in greater than 50% of the tumor cells (present in this case), was associated with a specificity of 0.99 for squamous cell carcinomas. The final diagnosis, therefore, is as follows:

Mesenteric mass, biopsy:

Metastatic, poorly differentiated carcinoma most consistent with poorly differentiated squamous cell carcinoma.

NOTE: Case was discussed with +4200

Addendum Signed: Electronically Signed

+4200

ADDENDUM DIAGNOSIS #1

A panel of immunoperoxidase stains has been completed. The tumor cells are strongly immunoreactive for CK7 and CK5/6. They are negatively reactive for CK20, gross cystic disease fluid protein-15, Napsin A, TTF1, estrogen receptors and progesterone receptors. The findings support a diagnosis of metastatic carcinoma. However, the staining pattern is not characteristic of a breast primary. Furthermore, while CK7 is typically seen in carcinomas of glandular differentiation, the strong immunoreactivity for CK5/6 suggests a carcinoma of squamous or urothelial origin.

[page 2 of 19]
[REDACTED]

Patient: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED]

+4185

Additional immunohistochemical stains have been ordered and these will hopefully help differentiate between a carcinoma of glandular vs nonglandular origin. The results will follow as an addendum. The original diagnosis has been modified as follows:

FINAL DIAGNOSIS

Mesenteric mass, biopsy:

Metastatic, poorly differentiated carcinoma.

Case discussed with [REDACTED]

+4194

Addendum Signed: Electronically Signed [REDACTED]

+4194

FINAL DIAGNOSIS

Mesenteric mass, biopsy:

Metastatic adenocarcinoma (see comment).

COMMENT: The histologic findings would be consistent with a breast primary. Immunohistochemistries for estrogen receptors, progesterone receptors and Her2-neu will be performed. An addendum will follow.

Diagnosed By: [REDACTED]

+4186

GROSS DESCRIPTION

The specimen, received in formalin labeled "left mesenteric mass", consists of multiple cylindrical needle core biopsies of soft gray tissue measuring up to 1.0 cm in length. They are entirely submitted in one cassette labeled 1A. [REDACTED]

MICROSCOPIC DESCRIPTION

[REDACTED]

[page 3 of 19]
[REDACTED]

PATHOLOGY REPORT

[REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED]

+4185

Microscopic examination performed.

CLINICAL HISTORY

History of breast cancer

COPIES TO

[REDACTED]

Signed: [REDACTED]

Electronically Signed By: [REDACTED]

+4186

[page 4 of 19]
Patient Name:
MR#:
Acct:
DOB:

Phys:
Reading Phys:
Exam Date:
Loc:

+4179

EXAM# TYPE/EXAM

CT CHEST ABDOMEN PELVIS WITH CONTRAST

+4179

CLINICAL INFORMATION: Breast cancer. Left lower quadrant pain for a month. History left mastectomy and appendectomy.

PROCEDURE: CT Chest, abdomen, and pelvis following intravenous administration 100cc's Isovue 300.

+4149

COMPARISON: CT abdomen pelvis older studies from have been archived and not available for review

+419

FINDINGS: There is a large mass in the left upper lobe measuring 9.2 cm. This is along the margin of the upper left mediastinum and also extends anteriorly to the pleural surface. No associated rib destruction and no definite extension through the chest wall. No other lung masses. Mild nodularity near the carina likely due to secretions. Mastectomy on the left. No axillary or mediastinal adenopathy cysts. No pleural or pericardial effusion. Mass in the inferior margin right lobe of the liver is ill-defined and estimated to be measuring 3.7 cm and this was not clearly seen previously. There may be smaller mass just anterior to the gallbladder fossa measuring 1.4 cm. Gallbladder present with gallstones. Spleen is not enlarged. No pancreatic masses and no adrenal masses. Left kidney unremarkable. There is however a solid mass involving the mid to lower pole right kidney which be concerning for renal cell cancer or metastatic disease. This is measuring up to 3.8 cm and has not changed significantly. Aorta is atherosclerotic. Small amount of ascites in the pelvis. Necrotic mass is identified in the left lower quadrant. This area was not imaged on the prior CT abdomen. The mass is measuring up to 8.9 cm. Mildly enlarged lymph nodes are also present within the retroperitoneum of the upper abdomen. There is also a masslike area involving the cecum measuring 4.4 cm. No evidence of bowel obstruction. Degenerative changes are present within the spine.

IMPRESSION:

[page 5 of 19]
Exam#: [REDACTED] CT CHEST WITH CONTRAST

Findings include a large mass in the left upper lobe, at least one mass in the liver, solid mass in the right kidney, large mass in the lower left mesentery, and mass within the cecum. Findings could all be on the basis of metastatic disease relating to the history of breast cancer. Alternatively, a primary lung, renal, or GI malignancy could be present with associated metastatic findings.

Electronically Signed By: [REDACTED]

SD/ST: [REDACTED] +4179

Technologist: [REDACTED]

CC: [REDACTED]

[page 6 of 19]
[REDACTED]

[REDACTED]

[REDACTED]

+4758

EXAM# TYPE/EXAM

[REDACTED]

CT CHEST ABDOMEN PELVIS WITH CONTRAST [REDACTED]

+4758

+0

CLINICAL INFORMATION: Lung cancer in [REDACTED] 4179 and breast cancer [REDACTED] with metastatic disease. Status post chemotherapy and radiation therapy.

PROCEDURE: CT Chest, abdomen, and pelvis following intravenous administration 100cc's Isovue 300.

+4669

COMPARISON: [REDACTED] and older

FINDINGS: Chest port on the left. Left apical scarring and air collection unchanged. Mild pleural thickening anterior aspect of the lingula without significant change. No lung mass. No axillary or mediastinal lymphadenopathy. No pleural or pericardial effusion. Surgical clips in the left axilla. Left mastectomy. No liver mass. Gallbladder with mildly thickened wall. Trace pericholecystic fluid could not be excluded although the appearance is essentially unchanged from the prior. Spleen is not enlarged. Pancreas and adrenal glands unremarkable. 2 mm calculus lower pole right kidney. No suspicious renal mass or hydronephrosis. Aortic and iliac atherosclerosis. Uterus present. No adnexal masses. Urinary bladder unremarkable. No ascites. Large amount of stool within the colon. No inflammatory changes in the mesentery. No pelvic or retroperitoneal lymphadenopathy. No free air. Degenerative changes in the spine. No destructive bone lesions.

Impression:

1. No evidence of metastatic or recurrent malignancy.
2. Mildly abnormal appearance of the gallbladder which has not changed significantly. Ultrasound correlation recommended particularly if there are right upper quadrant symptoms.
3. Postoperative changes left hemithorax. Left mastectomy and axillary node dissection.
4. Exam detailed above.

[page 7 of 19]
[REDACTED]

Electronically Signed By: [REDACTED]

SD/ST: [REDACTED]

+4758

Technologist: [REDACTED]

CC: [REDACTED]

[page 8 of 19]
+5516

EXAM# TYPE/EXAM

CT chest, abdomen and pelvis

HISTORY: History of breast and lung cancer. Status post chemotherapy and radiation therapy.

FINDINGS: Transverse imaging was performed through the chest, abdomen and pelvis with oral contrast and intravenous injection of 100 mL Isovue-300. Coronal reformat imaging was performed. Comparison is made
+5312 to [REDACTED] Left mastectomy changes with axillary lymph node dissection is again demonstrated. Mild density compatible with fibrosis in the anterior left lung is again demonstrated. No acute pulmonary infiltrate or pleural effusion is apparent. There is minimal fibrosis in the base of the right lung. The tip of the left approach central line is obscured by intravascular contrast. The left lobe of the thyroid remains small. No new mediastinal lymphadenopathy is identified. The heart is not enlarged. Arterial calcifications including coronary artery calcifications are present. Diminished density compatible with fatty infiltration is again noted in the liver. Mild wall thickening in the gallbladder with subtle findings compatible with stones is again demonstrated. No new biliary ductal dilatation is identified. No new mass is evident in the liver or adrenal glands. The abdominal aorta is not enlarged. There are nonenlarged para-aortic lymph nodes in the abdomen. There is no hydronephrosis. A small hypodensity arising from the inferior left kidney and cortical scarring in the inferior right kidney with a small calcification is again demonstrated. The pancreas and spleen appear normal. No dilated bowel is identified. The uterus is not enlarged. There is no free fluid in the pelvis. No pelvic lymphadenopathy is identified. There is advanced degenerative disease in the spine.

IMPRESSION:

1. No interval changes to suggest new or progressive metastatic disease in the chest, abdomen or pelvis.
2. Stable left pulmonary opacities that may represent fibrosis.
3. Left mastectomy and axillary lymph node dissection.
4. Gallbladder wall thickening with probable cholelithiasis is again

[page 9 of 19]
[REDACTED]

demonstrated.

5. Stable appearing kidneys with a small hypodensity on the left and mild cortical scarring with a calcification on the right again demonstrated.

6. Atherosclerotic disease and degenerative disease.

The CT scan was performed using automatic exposure control (Care Dose or Smart MA). If appropriate, the dose was adjusted for patient age and weight. Pediatric specific protocols are used in children. If clinically appropriate, the scan may use Iterative Reconstruction to further reduce radiation exposure.

This document was created using voice recognition. If errors are found, they need to be taken into context.

Electronically Signed By: [REDACTED]

SD/ST: [REDACTED] +5516

Technologist: [REDACTED]

CC: [REDACTED]

[page 10 of 19]
Phys:
Reading Phys:
Exam Date:
Loc:

+4255

EXAM# TYPE/EXAM

CT CHEST, ABDOMEN AND PELVIS WITH CONTRAST

CLINICAL INDICATION: Left lower quadrant pain. Multiple metastases. History of breast cancer.

Technique: Multislice helical with oral and 100 mL Isovue-300 IV contrast.

FINDINGS: The large left upper lobe pleural-based mass has decreased in size and developed central air since [REDACTED] and now measures 6.5 x 6.3 cm (9.2 cm previously). Paratracheal, AP window and subcarinal lymph nodes have developed measuring up to 2.1 cm. There is also a para-aortic nodule adjacent to the main mass. There are no new pulmonary nodules. There are left upper lobe groundglass and linear opacities. The heart size is normal. There are aortic and coronary artery atheromatous calcifications. The left breast has been resected. Surgical clips in the left axilla are probably from a prior lymph node dissection. A right thyroid nodule is unchanged. The right renal mass has decreased in size and now measures 2.3 cm. The bilateral pelvic masses have significantly decreased in size and essentially resolved. The right hepatic mass has significantly decreased in size and now measures approximately 1.4 cm. Fatty liver infiltration is mild and diffuse. Gallstones are again suggested. The tiny cyst in the lower pole of the left kidney is unchanged. The left suprarenal lesion has not significantly changed. The other visualized abdominal and pelvic viscera are stable. A right thoracolumbar scoliosis is mild.

IMPRESSION:

1. Significantly decreased multiple metastases (left upper lobe, right hepatic, right kidney and bilateral pelvis). Mediastinal lymph nodes. Left suprarenal lesion, not significantly changed.
2. Cholelithiasis: Mild hepatic steatosis.
3. Tiny left renal cyst, unchanged.
4. Right thyroid nodule, unchanged.
5. Calcific coronary artery disease.

[page 11 of 19]
Exam#: [REDACTED] CT CHEST WITH CONTRAST

Electronically Signed By: [REDACTED]
SD/ST: [REDACTED] +4255

Technologist: [REDACTED]

CC: [REDACTED]

[page 12 of 19]
Phys:
Reading Phys:
Exam Date:
Loc:

+4283

EXAM# TYPE/EXAM

CT CHEST, ABDOMEN AND PELVIS +4283

HISTORY: Metastatic breast cancer. Chemotherapy and radiation therapy.
History of left mastectomy and appendectomy.

FINDINGS: Transverse imaging was performed through the chest, abdomen and pelvis with oral contrast and intravenous injection of 100 mL Isovue-300. Coronal reformat imaging was performed. Left mastectomy changes are demonstrated. There is a cavitary pleural-based mass in the anterior upper lobe of the left lung. At similar levels the mass measures 6.7 x 6.2 cm compared to 7.0 x 6.6 cm previously. Mild stranding in the lung adjacent to the mass is again noted. There is mildly increased 0.8 x 2.0 cm pleural-based density in the anterior margin of the upper lobe of the left lung inferiorly, series 5 image 36. Slight density compatible with atelectasis or fibrosis in the base of the right lung is again noted. There are no pleural effusions. The small nodule along the anterior margin of the right lobe of the thyroid appears stable. There is a stable mildly prominent precarinal lymph node. No new mediastinal lymphadenopathy is apparent. The heart is not enlarged. Arterial calcifications are demonstrated. There is subtle density compatible with stones in the gallbladder. Mild wall thickening in the gallbladder cannot be excluded. A hypodensity in the inferior right lobe of the liver posteriorly does not appear significantly changed measuring 1.9 cm compared to 2 cm previously. No new lesions are identified in the liver. The adrenal glands are not enlarged. At similar levels the hypodensity in the inferior right kidney measures 1.8 cm compared to 2.1 cm previously. A small hypodensity in the inferior margin of the left kidney is again noted. There is no hydronephrosis. The spleen appears stable. No new lymphadenopathy is identified in the para-aortic region. The pancreas appears stable with mild atrophy or volume loss again demonstrated. The uterus is not enlarged. There is contrast through the small bowel in the majority of the colon. There is multilevel degenerative disease in the spine. There is dextrosciosis of the lumbar spine.

IMPRESSION:

1. The cavitary mass in the left lung is mildly improved. There is a small plaque-like pleural-based density in the lung inferior to this level. This is more prominent on today's study but could represent

[page 13 of 19]
Exam#: [REDACTED] CT CHEST WITH CONTRAST

focal atelectasis or radiation changes rather than a developing nodule. Otherwise no significant change is noted in the chest with mild stable mediastinal lymph node enlargement and stable nodularity along the margin of the right lobe of the thyroid.

2. No interval changes to suggest new or progressive metastatic disease are identified in the abdomen and pelvis. The hypodensity in the liver does not appear significantly changed. The hypodensity in the kidney is mildly improved. There is a small stable hypodensity in the left kidney.

3. There are subtle findings suggesting cholelithiasis. There may be some wall thickening in the gallbladder as could be seen with cholecystitis. Ultrasound is recommended as clinically indicated. There is borderline prominence of the biliary ducts.

Electronically Signed By: [REDACTED]

SD/ST: [REDACTED] +4283

Technologist: [REDACTED]

CC: [REDACTED]

[page 14 of 19]
██████████ BL imaging = 2 weeks before start of most recent therapy
(BL = date of baseline imaging compared to date of first therapy that led to exceptional response.
For this case, imaging was available 2 weeks before most recent therapy)

[page 15 of 19]
Level 1 case

Large LUL mass on 1st 2 image sets.
Residual mass vs scar on last set.
C+CT images, various windows.

BL = 2 weeks before most recent
therapy started, upper row.
90 x 90 mm

BL + 3.5 months = 104 days later,
middle row.
61 x 68 mm; partially necrotic center

BL + 3.7 years = 1336 days after BL
imaging, lower row.

[page 16 of 19]
Level 1 case

C+CT

Possible liver mass , 38 x 35 mm - barely seen on BL axial image (upper LT image) - not seen on coronal view (RT images).

Not seen on follow up.

BL = 2 weeks before most recent therapy started, upper row.

BL + 3.5 months = 104 days later, middle row.

BL + 3.7 years = 1336 days after BL imaging, lower row.

[page 17 of 19]
Level 1 case

[page 18 of 19]
Level 1 case

Large central mesenteric mass in the pelvis
C+CT, axial images (LT column) and coronal images (RT column)

BL = 2 weeks before most recent therapy started, upper row.
Large central mesenteric mass in the pelvis, measured at over 80 mm, also marked with small red star.

BL + 3.5 months = 104 days later, middle row.
Fully resolved.

BL + 3.7 years = 1336 days after BL imaging, lower row.
Fully resolved on most recent images.

[page 19 of 19]
Level 1 case

BL imaging

Cecal (RT) and mesenteric (center) masses
C+CT, axial images (LT column) and sagittal or coronal images (RT column)

BL = 2 weeks before most recent therapy started, upper row.
Cecal mass (RT)
Measured, 52 x 55 x 46 mm, and multiple yellow arrows.
Large central mesenteric mass in the pelvis, multiple orange arrows.

BL + 3.5 months = 104 days later, middle row.
Both masses fully resolved

BL + 3.7 years = 1336 days after BL imaging, lower row.
Both masses fully resolved on most recent images.

Source: NCI Genomic Data Commons file 3566e6cb-7a65-449d-896b-00543647ebbd (ER0428 ER-B0BP Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).